Somatic mutation profile of tumor specimen MP2PRT-PAUFSB-TMP1-A (aliquot MP2PRT-PAUFSB-TMP1-A-1-0-D-A818-36) from MP2PRT case MP2PRT-PAUFSB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.6 years (932 days).
Specimen MP2PRT-PAUFSB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 876078e7-75c8-4181-b9ea-7736308bae29.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUFSB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUFSB-NB1-A-1-0-D-A818-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b22a53f3-3fc9-4545-a7b2-02a1ce5e0af4

The open-access MAF lists 17 somatic variants for this specimen: 15 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 15, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4414T>G p.W1472G | Missense Mutation (SNP) | VAF 39/314 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52115485, COSV52123447, COSV52128448; called by muse, mutect2, varscan2
- KRAS | c.351A>T p.K117N | Missense Mutation (SNP) | VAF 17/185 reads (9%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs770248150, COSV55504752, COSV55545304; ClinVar: pathogenic; called by muse, mutect2
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 66/313 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CCDC39 | c.2636C>G p.S879C | Missense Mutation (SNP) | VAF 28/230 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756225920; called by muse, mutect2, varscan2
- CRACD | c.2728C>T p.R910W | Missense Mutation (SNP) | VAF 111/859 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV99949024; called by muse, mutect2, varscan2
- MROH2A | c.2573C>T p.A858V | Missense Mutation (SNP) | VAF 34/258 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.026); catalogued as rs907643173; called by muse, mutect2, varscan2
- PCDHB3 | c.1919T>A p.L640Q | Missense Mutation (SNP) | VAF 109/921 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1554272613; called by muse, mutect2, varscan2
- PLEC | c.6614C>T p.T2205M (on ENST00000322810 / NM_201380.4; = p.T2095M on NM_000445.5) | Missense Mutation (SNP) | VAF 120/583 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.851); catalogued as rs781943555; called by muse, varscan2
- TMEM198 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 125/687 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.848); catalogued as rs758187620, COSV99523466; called by muse, mutect2, varscan2
- ZBED6CL | c.62G>A p.R21H | Missense Mutation (SNP) | VAF 200/517 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.025); catalogued as rs770853622, COSV59604428; called by muse, mutect2, varscan2
- ATP8B2 | c.1078T>G p.F360V (on ENST00000672630; = p.F327V on NM_001005855.2) | Missense Mutation (SNP) | VAF 22/516 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2
- NEK11 | c.1811T>A p.I604N | Missense Mutation (SNP) | VAF 33/355 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.362); called by muse, mutect2
- RASSF8 | c.579T>G p.F193L | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT tolerated (0.66); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SORCS3 | c.1289A>C p.Y430S | Missense Mutation (SNP) | VAF 38/315 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- STN1 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 65/461 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NTRK3 | c.1197C>A p.P399= | Silent (SNP) | VAF 103/235 reads (44%) | catalogued as COSV100448413; called by muse, mutect2, varscan2
- TSHZ3 | c.2349C>T p.H783= | Silent (SNP) | VAF 126/375 reads (34%) | catalogued as rs368039667; called by muse, mutect2, varscan2
